Surgical pathology report (de-identified scan), TCGA case TCGA-19-0957, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Case Western, specimen TCGA-19-0957-01C (Primary Tumor).

TCGA-19-0957
(0957)

SURGICAL PATHOLOGY REPORT

Name:
Accession #:
Date of Procedure:
Date Received:

FINAL DIAGNOSIS

A., B. LEFT BRAIN LESION, BIOPSY AND REMOVAL:
-- GLIOBLASTOMA MULTIFORME (WHO GRADE IV).

Electronically Signed Out By By the signature on this report, the individual or group listed as making the Final Interpretation/Diagnosis certifies

Intraoperative Consult Diagnosis

A. Microscopic: Glioblastoma.

Addendum/Procedures: ANCILLARY TESTING

Date Ordered:
Date Complete:
Date Reported:

Status: Complete

Clinical History:

Left brain lesion

Specimens Submitted As:

A: LEFT BRAIN LESION BX
B: LEFT BRAIN LESION

Gross Description:

A: Received fresh for intraoperative consultation, labeled with the patient's name, hospital number and "left brain lesion BX," are fragments of light tan and dark red to brown soft tissue measuring 1.2 x 0.9 x 0.5 cm. in aggregate. Part of the specimen is frozen and part is submitted for touch preparation. Entirely submitted in two cassettes.

B: Received fresh, labeled with the patient's name, number, and [REDACTED] are multiple light tan pink irregular soft tissue fragments measuring 3.2 x 3.0 x 0.6 cm. A portion of tissue is given to [REDACTED]. Submitted in toto in 4 cassettes.

Summary of Cassettes:

Specimen	Label	Site
A	1FS	
	2	remainder of specimen

Source: NCI Genomic Data Commons file cefb42af-191e-4a05-916e-9ff1d083e256 (TCGA-19-0957.9836EF10-B376-4BA2-8C95-642D18A3EDD1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).